Somatic mutation profile of tumor specimen ALCH-ABE2-TTP1-A (aliquot ALCH-ABE2-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABE2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.9 years (20,790 days).
Specimen ALCH-ABE2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 950072a1-b074-4c48-b822-0b3016c42388.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABE2-NB1-A (Blood Derived Normal), aliquot ALCH-ABE2-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ec78677-752a-4e12-a59d-9a3c01870460

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD33B | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV56980706; called by muse, mutect2, varscan2
- H2BC4 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as COSV58417765; called by muse, mutect2
- ILKAP | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1273069652, COSV54519388, COSV99610994; called by muse, mutect2
- ADGRG1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 34/797 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.686); called by muse, mutect2
- ATP2A1 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- C1orf74 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2
- CMTM2 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DAG1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2
- DAP | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- ERVMER34-1 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- JUP | c.860T>G p.I287S | Missense Mutation (SNP) | VAF 44/567 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MACF1 | c.19766C>A p.S6589Y (on ENST00000372915; = p.S4634Y on NM_012090.5) | Missense Mutation (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- MTA2 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 28/702 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NSD1 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- PCDHGA1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); called by muse, mutect2
- SLC49A3 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- SRRM2 | c.6148A>G p.I2050V | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZFP62 | c.1352G>C p.C451S (on ENST00000502412 / NM_001377944.1; = p.C418S on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATL1 | c.687C>T p.A229= | Silent (SNP) | VAF 24/868 reads (3%) | catalogued as rs921388034; ClinVar: likely benign; called by muse, mutect2
- CHD8 | c.5985A>G p.S1995= (on ENST00000646647 / NM_001170629.2; = p.S1716= on NM_020920.4) | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- NF1 | c.6843A>G p.G2281= (on ENST00000358273 / NM_001042492.3; = p.G2260= on NM_000267.3) | Silent (SNP) | VAF 45/603 reads (7%) | catalogued as COSV62198087; called by muse, mutect2
- NIM1K | c.639C>T p.G213= | Silent (SNP) | VAF 45/438 reads (10%) | catalogued as rs1368386873, COSV58143400; called by muse, mutect2
- RAB6A | c.*11C>G | 3'UTR (SNP) | VAF 24/529 reads (5%) | called by muse, mutect2
- ZFP69B | c.341-38G>A | Intron (SNP) | VAF 30/640 reads (5%) | called by muse, mutect2
